Somatic mutation profile of tumor specimen TCGA-IG-A3QL-01A (aliquot TCGA-IG-A3QL-01A-11D-A247-09) from TCGA case TCGA-IG-A3QL, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 54.1 years (19,755 days).
Specimen TCGA-IG-A3QL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec735147-e4ca-40e9-8836-7e8aace5cabe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A3QL-10A (Blood Derived Normal), aliquot TCGA-IG-A3QL-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b0ab1d8-8a21-4455-829b-b7a879e32b2a

The open-access MAF lists 108 somatic variants for this specimen: 73 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 32, Nonsense Mutation 5, Frame Shift Del 3, Splice Region 2, Frame Shift Ins 2, RNA 1, Splice Site 1, 3'UTR 1, In Frame Del 1, Nonstop Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.749_751del p.P250_I251delinsL | In Frame Del (DEL) | VAF 56/64 reads (88%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACACA | c.3698C>T p.T1233M | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs1056165767; called by muse, mutect2, varscan2
- CBLIF | c.57T>A p.S19R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as rs762525615; called by muse, mutect2
- CHRM2 | c.451T>A p.S151T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57769127, COSV57775493; called by muse, mutect2, varscan2
- CIITA | c.2522C>T p.T841M | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs1159888268; called by muse, mutect2, varscan2
- DCAF12 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as rs764970375; called by muse, mutect2, varscan2
- DMRT2 | c.1144C>G p.R382G | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.099); catalogued as rs760681935; called by muse, mutect2, varscan2
- ESPNL | c.2800G>A p.A934T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs746042812, COSV58033749; called by muse, mutect2, varscan2
- FAM135B | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.563); catalogued as COSV50535040; called by muse, mutect2, varscan2
- FLCN | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1261069493; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNDC3A | c.1904G>A p.R635H (on ENST00000492622 / NM_001079673.2; = p.R579H on NM_014923.5) | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs367719937; called by muse, mutect2, varscan2
- KASH5 | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as rs967303029; called by muse, mutect2, varscan2
- KIAA1549 | c.4804C>T p.R1602C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758674277; called by muse, mutect2, varscan2
- MACROH2A1 | c.174G>A p.A58= | Splice Region (SNP) | VAF 13/32 reads (41%) | catalogued as rs141756450; called by muse, mutect2, varscan2
- MSH6 | c.3820G>C p.E1274Q | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs587779294, COSV52288158; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NINL | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs766249914, COSV54001160; called by muse, mutect2, varscan2
- NPBWR2 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753109352; called by muse, mutect2, varscan2
- OR52N5 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs372227128; called by muse, mutect2, varscan2
- OR9A4 | c.542G>C p.R181P | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.745); catalogued as rs782482254, COSV71885099; called by muse, mutect2
- PRDX1 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1159513963; called by muse, mutect2
- PTCH1 | c.2042del p.P681Rfs*12 | Frame Shift Del (DEL) | VAF 38/56 reads (68%) | catalogued as COSV59461975; called by mutect2, pindel, varscan2
- SIGLEC9 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs113526831; called by muse, mutect2, varscan2
- SLC9C2 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs539570027, COSV62946320, COSV62947742; called by muse, mutect2, varscan2
- TPGS2 | c.903A>T p.*301Cext*32 | Nonstop Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV57541106; called by muse, mutect2, varscan2
- ZNF264 | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as rs751802283, COSV54040600; called by muse, mutect2, varscan2
- ZNF43 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as rs1322616094; called by muse, mutect2, varscan2
- ZNF599 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as rs143039488; called by muse, mutect2, varscan2
- ABCC3 | c.1750A>G p.M584V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADCY1 | c.522dup p.A175Cfs*62 | Frame Shift Ins (INS) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- AJUBA | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 13/15 reads (87%) | called by muse, varscan2
- AKAP13 | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ALPK2 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2
- BRAF | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- CAD | c.3181A>T p.S1061C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CALCB | c.62G>C p.G21A | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- CATSPER2 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | called by mutect2, varscan2
- CFAP47 | c.5076T>G p.F1692L | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP2C9 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DRD2 | c.991G>C p.A331P | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ELAPOR2 | c.1198C>A p.P400T (on ENST00000450689 / NM_001142749.3; = p.P233T on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FAM135B | c.782T>A p.V261E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FBXL22 | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FLI1 | c.650A>C p.K217T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- HOXB5 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- IFT122 | c.1058G>T p.S353I (on ENST00000348417 / NM_052989.3; = p.S294I on NM_018262.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IGLV1-50 | c.151G>C p.G51R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- JAG2 | c.3152C>T p.A1051V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- KDR | c.602A>T p.E201V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- KMT2C | c.6232A>G p.T2078A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LAMC1 | c.2225G>T p.C742F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP12 | c.1565G>C p.R522T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MAMDC4 | c.820_823del p.E274Qfs*74 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- MPPED2 | c.565A>G p.N189D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- MYO3A | c.2262+2T>A p.X754_splice | Splice Site (SNP) | VAF 31/33 reads (94%) | called by muse, mutect2, varscan2
- OCM | c.2_8dup p.T4_?3 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | called by mutect2, varscan2
- OR14K1 | c.730A>G p.I244V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PRKCSH | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- PSTK | c.51A>T p.K17N | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTCH2 | c.1292del p.L431Rfs*103 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | called by mutect2, pindel, varscan2
- SAMD9L | c.3959G>T p.S1320I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- SCN8A | c.2808G>C p.E936D | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEMA6C | c.759G>A p.V253= | Splice Region (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- SLC45A2 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- SLX4 | c.918G>A p.M306I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPAG9 | c.1111G>T p.E371* (on ENST00000262013 / NM_001130528.3; = p.E357* on NM_003971.6) | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- SSX5 | c.253G>A p.D85N (on ENST00000347757 / NM_175723.1; = p.D126N on NM_021015.4) | Missense Mutation (SNP) | VAF 54/81 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SZT2 | c.7704G>T p.M2568I (on ENST00000634258 / NM_001365999.1; = p.M2511I on NM_015284.4) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.061); called by muse, mutect2
- TMPRSS9 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- UNC13C | c.4252A>G p.I1418V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- WDR83 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZDHHC23 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZNF496 | c.1649C>A p.A550D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AHNAK | c.9090C>T p.F3030= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV57229333; called by muse, mutect2, varscan2
- ANO5 | c.2178C>T p.S726= | Silent (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- ARID4A | c.2773C>T p.L925= | Silent (SNP) | VAF 15/18 reads (83%) | called by muse, mutect2, varscan2
- CELF2 | c.411A>C p.G137= (on ENST00000416382 / NM_001025077.3; = p.G144= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- CHD7 | c.5934A>T p.V1978= | Silent (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2, varscan2
- DCAF12 | c.1008C>A p.S336= | Silent (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.474G>C p.L158= | Silent (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- EPHA10 | c.2430G>T p.A810= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs780958682, COSV57624881; called by mutect2, varscan2
- FAM71F1 | c.951C>T p.S317= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs774672617, COSV59372747; called by muse, mutect2, varscan2
- FLG | c.4011C>A p.S1337= | Silent (SNP) | VAF 57/291 reads (20%) | catalogued as COSV64250068; called by muse, mutect2, varscan2
- FLNA | c.2466C>A p.I822= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV61050167; called by muse, mutect2, varscan2
- LRIG1 | c.1386C>A p.A462= | Silent (SNP) | VAF 21/24 reads (88%) | called by muse, varscan2
- LRRC23 | c.555G>A p.E185= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV99145171, COSV99145395; called by muse, mutect2, varscan2
- MAML2 | c.291C>T p.A97= | Silent (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
- MCF2L2 | c.1866C>T p.R622= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- MEP1A | c.495C>T p.H165= | Silent (SNP) | VAF 57/70 reads (81%) | catalogued as rs776751972, COSV57922445; called by muse, mutect2, varscan2
- MYH11 | c.2791C>T p.L931= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as rs1260021976; called by muse, mutect2, varscan2
- NRROS | c.837G>A p.L279= | Silent (SNP) | VAF 27/50 reads (54%) | called by muse, mutect2, varscan2
- NUDT5 | c.600C>T p.Y200= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs148632115; called by muse, mutect2, varscan2
- PML | c.2280C>T p.S760= | Silent (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2
- PRAME | c.1005G>A p.S335= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs185120829; called by muse, mutect2, varscan2
- RHBDF1 | c.2271C>T p.F757= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs753678236; called by muse, mutect2, varscan2
- RRS1 | c.813G>T p.L271= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs765188633; called by muse, varscan2
- SLC16A5 | c.519T>A p.L173= | Silent (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- SLC5A9 | c.423G>T p.L141= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- SLC6A16 | c.1261C>T p.L421= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV100242811; called by muse, mutect2, varscan2
- SPTA1 | c.4509A>G p.K1503= | Silent (SNP) | VAF 31/52 reads (60%) | called by muse, mutect2, varscan2
- TAS2R8 | c.309T>C p.L103= | Silent (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- TIAM1 | c.3228C>T p.L1076= | Silent (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- TRIM49 | c.345C>T p.C115= | Silent (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- USH1G | c.981C>T p.H327= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as rs1334593284, COSV58883871; called by muse, mutect2, varscan2
- ZNF486 | c.915T>C p.H305= | Silent (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- CEACAM18 | c.-16G>A | 5'UTR (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- LGR4 | c.*1A>T | 3'UTR (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- ZNF767P | n.521G>T | RNA (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
